Somatic mutation profile of tumor specimen TCGA-29-1703-01A (aliquot TCGA-29-1703-01A-01W-0633-09) from TCGA case TCGA-29-1703, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G2; Age at diagnosis: 56.5 years (20,622 days).
Specimen TCGA-29-1703-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0c045474-26ee-4ab1-805b-8919c06feea7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-29-1703-10A (Blood Derived Normal), aliquot TCGA-29-1703-10A-01W-0633-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/da2adca0-234e-4309-8072-1c8eeda97815

The open-access MAF lists 86 somatic variants for this specimen: 63 protein-altering or splice-affecting, 19 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 52, Silent 19, Splice Site 6, Frame Shift Del 2, Intron 2, Nonsense Mutation 2, 3'Flank 1, Frame Shift Ins 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RB1 | c.1215+1G>A p.X405_splice | Splice Site (SNP) | VAF 169/361 reads (47%) | hotspot (GDC flag); catalogued as rs587776783, CS890133, CS982341, COSV57294684, COSV57294939, COSV57306748; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.577C>T p.H193Y | Missense Mutation (SNP) | VAF 111/125 reads (89%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs876658468, COSV52675896, COSV52688299, COSV52757395; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCF2 | c.509C>T p.A170V | Missense Mutation (SNP) | VAF 26/53 reads (49%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as COSV55186067; called by muse, mutect2, varscan2
- AP1G2 | c.1402A>T p.I468F | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.756); catalogued as COSV55339545; called by muse, mutect2, varscan2
- APOBR | c.2977G>A p.V993M (on ENST00000431282; = p.V1002M on NM_018690.4) | Missense Mutation (SNP) | VAF 28/89 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs1297568537, COSV60493474; called by muse, mutect2, varscan2
- ARHGEF38 | c.502G>T p.V168L | Missense Mutation (SNP) | VAF 90/319 reads (28%) | SIFT tolerated (0.2); PolyPhen benign (0.015); catalogued as rs773427927, COSV54444858; called by muse, mutect2, varscan2
- CACNA2D3 | c.1204G>A p.A402T | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.07); catalogued as COSV55573525; called by muse, mutect2, varscan2
- CDC42BPA | c.2587-1G>C p.X863_splice | Splice Site (SNP) | VAF 157/649 reads (24%) | catalogued as COSV62018582; called by muse, mutect2, varscan2
- CFH | c.2899G>T p.G967W | Missense Mutation (SNP) | VAF 94/331 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66405801, COSV66412245; called by muse, mutect2, varscan2
- CREBBP | c.4280+1G>T p.X1427_splice | Splice Site (SNP) | VAF 22/64 reads (34%) | catalogued as COSV52137852; called by muse, mutect2, varscan2
- CTC1 | c.1547C>T p.P516L | Missense Mutation (SNP) | VAF 42/89 reads (47%) | SIFT tolerated (0.11); PolyPhen benign (0.062); catalogued as rs747574053, COSV59854990; called by muse, mutect2, varscan2
- DNAJC1 | c.1184A>G p.Q395R | Missense Mutation (SNP) | VAF 19/94 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.17); catalogued as rs1203151536, COSV65413612; called by muse, mutect2, varscan2
- DNAJC6 | c.2296C>T p.R766C | Missense Mutation (SNP) | VAF 53/158 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs758563843, COSV54780531; called by muse, mutect2, varscan2
- DOCK8 | c.6137T>A p.L2046H | Missense Mutation (SNP) | VAF 51/145 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV66623194; called by muse, mutect2, varscan2
- EPB41L3 | c.1957G>A p.A653T | Missense Mutation (SNP) | VAF 139/260 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); catalogued as rs201249884, COSV100549782; called by muse, mutect2, varscan2
- ERO1B | c.1016C>A p.T339K | Missense Mutation (SNP) | VAF 102/395 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.598); catalogued as COSV99934556; called by muse, mutect2, varscan2
- ETV4 | c.518C>A p.P173H | Missense Mutation (SNP) | VAF 63/68 reads (93%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.977); catalogued as COSV60045286; called by muse, mutect2, varscan2
- FAM111A | c.943A>C p.K315Q | Missense Mutation (SNP) | VAF 80/158 reads (51%) | SIFT tolerated (0.09); PolyPhen benign (0.044); catalogued as COSV64655791; called by muse, mutect2, varscan2
- FAM120C | c.2260C>T p.L754F | Missense Mutation (SNP) | VAF 146/219 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60261962; called by muse, mutect2, varscan2
- FAM135A | c.3712G>A p.V1238I (on ENST00000370479 / NM_001351599.1; = p.V1025I on NM_020819.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 152/458 reads (33%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs777577366, COSV52057712; called by muse, mutect2, varscan2
- FAT4 | c.14389C>G p.L4797V | Missense Mutation (SNP) | VAF 74/234 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV58703970; called by muse, mutect2, varscan2
- FILIP1 | c.2981G>C p.S994T | Missense Mutation (SNP) | VAF 28/602 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.023); catalogued as COSV52726542; called by muse, mutect2
- FUT10 | c.707C>T p.T236I | Missense Mutation (SNP) | VAF 169/191 reads (88%) | SIFT tolerated (0.06); PolyPhen benign (0.234); catalogued as COSV59453811; called by muse, mutect2, varscan2
- GALNT13 | c.403G>T p.V135F | Missense Mutation (SNP) | VAF 55/217 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV67235277; called by muse, mutect2, varscan2
- GZF1 | c.1634G>A p.R545H | Missense Mutation (SNP) | VAF 50/160 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1041287600, COSV57637855; called by muse, mutect2, varscan2
- HRNR | c.263T>A p.I88N | Missense Mutation (SNP) | VAF 28/94 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.678); catalogued as COSV64260467, COSV64262024; called by muse, mutect2, varscan2
- HSDL2 | c.961C>G p.L321V | Missense Mutation (SNP) | VAF 210/681 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.078); catalogued as COSV52716844; called by muse, mutect2, varscan2
- KIF4B | c.2133C>G p.N711K | Missense Mutation (SNP) | VAF 12/234 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV101469282; called by muse, mutect2
- LMBRD1 | c.1235T>C p.I412T (on ENST00000649011; = p.I390T on NM_018368.4) | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65299019; called by muse, mutect2, varscan2
- MDH1B | c.215G>A p.R72H | Missense Mutation (SNP) | VAF 220/757 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); catalogued as rs374638364; called by muse, mutect2, varscan2
- MTURN | c.322G>C p.E108Q | Missense Mutation (SNP) | VAF 50/102 reads (49%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.445); catalogued as COSV61024321; called by muse, mutect2, varscan2
- NAV2 | c.4900+1G>T p.X1634_splice (on ENST00000396087 / NM_001244963.2; = p.X1611_splice on NM_145117.5) | Splice Site (SNP) | VAF 50/108 reads (46%) | catalogued as rs749522734, COSV60664211; called by muse, varscan2
- NFU1 | c.651C>G p.I217M (on ENST00000410022 / NM_001002755.4; = p.I193M on NM_015700.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 131/408 reads (32%) | SIFT tolerated (0.05); PolyPhen benign (0.309); catalogued as COSV58007447; called by muse, mutect2, varscan2
- NRG2 | c.858A>T p.K286N | Missense Mutation (SNP) | VAF 79/270 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as COSV56839437; called by muse, mutect2, varscan2
- OR5D13 | c.186C>A p.C62* | Nonsense Mutation (SNP) | VAF 22/245 reads (9%) | catalogued as COSV100686865; called by muse, mutect2
- PCDH19 | c.2939G>A p.R980H (on ENST00000373034 / NM_001184880.2; = p.R932H on NM_020766.3) | Missense Mutation (SNP) | VAF 123/266 reads (46%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.482); catalogued as rs368872920, COSV55269836; ClinVar: likely benign; called by muse, mutect2, varscan2
- PCSK2 | c.317G>A p.R106Q | Missense Mutation (SNP) | VAF 60/328 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs923748750, COSV52731452, COSV99360187; called by muse, mutect2, varscan2
- PHRF1 | c.556T>A p.C186S | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52761538; called by muse, mutect2, varscan2
- PLK1 | c.785G>A p.R262Q | Missense Mutation (SNP) | VAF 72/257 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1351133950, COSV55624002; called by muse, mutect2, varscan2
- PTCD2 | c.112C>G p.R38G | Missense Mutation (SNP) | VAF 27/63 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.022); catalogued as COSV54653246; called by muse, mutect2, varscan2
- QARS1 | c.509A>G p.D170G | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV60275985; called by muse, mutect2, varscan2
- RABL3 | c.606+1G>A p.X202_splice | Splice Site (SNP) | VAF 183/1125 reads (16%) | catalogued as rs1239744449, COSV99846494; called by muse, mutect2, varscan2
- RGS22 | c.3321C>G p.H1107Q | Missense Mutation (SNP) | VAF 234/1268 reads (18%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.543); catalogued as COSV62666543; called by muse, mutect2, varscan2
- SIRT4 | c.6G>C p.K2N | Missense Mutation (SNP) | VAF 108/240 reads (45%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as COSV99177429; called by muse, mutect2
- SMARCA2 | c.3346G>T p.G1116* | Nonsense Mutation (SNP) | VAF 24/388 reads (6%) | catalogued as COSV100570950; called by muse, mutect2
- SMG1 | c.2675G>C p.R892T | Missense Mutation (SNP) | VAF 43/168 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.95); catalogued as COSV67174341; called by muse, mutect2, varscan2
- SPIDR | c.1121G>A p.G374E | Missense Mutation (SNP) | VAF 64/230 reads (28%) | SIFT tolerated (0.7); PolyPhen benign (0.054); catalogued as rs773323462, COSV52388358; called by muse, mutect2, varscan2
- SPTA1 | c.3291G>C p.W1097C | Missense Mutation (SNP) | VAF 96/291 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100935559, COSV63758065; called by muse, mutect2, varscan2
- STC2 | c.310A>G p.K104E | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV54181764; called by muse, mutect2
- SUSD4 | c.382G>A p.E128K | Missense Mutation (SNP) | VAF 108/325 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs1272024616, COSV59552769; called by muse, mutect2, varscan2
- TDRD6 | c.2523A>G p.I841M | Missense Mutation (SNP) | VAF 51/160 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.612); catalogued as rs747359606, COSV60178060; called by muse, mutect2, varscan2
- TRPC4 | c.2515G>T p.V839L (on ENST00000379705 / NM_016179.4; = p.V844L on NM_003306.3) | Missense Mutation (SNP) | VAF 62/143 reads (43%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.05); catalogued as COSV59014332; called by muse, mutect2, varscan2
- UGGT2 | c.4477G>A p.A1493T | Missense Mutation (SNP) | VAF 136/144 reads (94%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as rs1173333361, COSV65078490; called by muse, mutect2, varscan2
- UNC13A | c.2384C>T p.S795L | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1336662157, COSV53202890; called by muse, mutect2
- USP19 | c.1984-1G>T p.X662_splice | Splice Site (SNP) | VAF 19/62 reads (31%) | catalogued as COSV100026077; called by muse, mutect2
- XPNPEP1 | c.560T>G p.I187S | Missense Mutation (SNP) | VAF 29/51 reads (57%) | SIFT deleterious (0); PolyPhen benign (0.219); catalogued as COSV59170730; called by muse, mutect2, varscan2
- ZNF574 | c.2209G>A p.G737S | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT tolerated (0.48); PolyPhen benign (0.087); catalogued as COSV55906516; called by muse, mutect2, varscan2
- ZRANB3 | c.1543G>A p.E515K | Missense Mutation (SNP) | VAF 60/188 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.058); catalogued as rs373989017; called by muse, mutect2, varscan2
- MROH1 | c.2237_2243dup p.A749Rfs*134 | Frame Shift Ins (INS) | VAF 10/34 reads (29%) | called by mutect2, varscan2
- PLEKHA7 | c.2300_2301del p.E767Vfs*3 | Frame Shift Del (DEL) | VAF 39/95 reads (41%) | called by pindel, varscan2
- TRGV3 | c.55T>A p.S19T | Missense Mutation (SNP) | VAF 184/451 reads (41%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- TRGV5 | c.55T>A p.S19T | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.975); called by mutect2, varscan2
- TRIML1 | c.1321del p.L441Sfs*24 | Frame Shift Del (DEL) | VAF 21/54 reads (39%) | called by mutect2, pindel, varscan2
- ANKRD26 | c.192G>A p.Q64= | Silent (SNP) | VAF 9/48 reads (19%) | catalogued as COSV65798082; called by muse, mutect2, varscan2
- ARSI | c.1134C>T p.S378= | Silent (SNP) | VAF 9/18 reads (50%) | catalogued as rs528847762, COSV60818250; called by muse, mutect2, varscan2
- ATP2A1 | c.2121C>T p.D707= | Silent (SNP) | VAF 22/67 reads (33%) | catalogued as rs767129999, COSV62870724; ClinVar: likely benign; called by muse, mutect2, varscan2
- CCR2 | c.702C>T p.N234= | Silent (SNP) | VAF 386/1169 reads (33%) | catalogued as rs371859867; called by muse, mutect2, varscan2
- CENPE | c.7495T>C p.L2499= | Silent (SNP) | VAF 41/129 reads (32%) | catalogued as rs202097843, COSV54388298; called by muse, mutect2, varscan2
- CFAP70 | c.402C>G p.P134= | Silent (SNP) | VAF 99/206 reads (48%) | catalogued as COSV60286281; called by muse, mutect2, varscan2
- CNTN4 | c.1578G>A p.S526= | Silent (SNP) | VAF 45/167 reads (27%) | catalogued as rs375250470; called by muse, mutect2, varscan2
- HHATL | c.501C>T p.G167= | Silent (SNP) | VAF 25/98 reads (26%) | catalogued as rs984622852, COSV60042918; called by muse, mutect2, varscan2
- MUC16 | c.17886C>T p.T5962= | Silent (SNP) | VAF 389/748 reads (52%) | catalogued as COSV67487925; called by muse, mutect2, varscan2
- MYT1L | c.733C>A p.R245= | Silent (SNP) | VAF 85/327 reads (26%) | catalogued as COSV67722156; called by muse, mutect2, varscan2
- NAV1 | c.2790T>G p.A930= | Silent (SNP) | VAF 97/344 reads (28%) | catalogued as COSV99818808; called by muse, mutect2
- NTMT1 | c.489C>T p.I163= | Silent (SNP) | VAF 25/40 reads (63%) | catalogued as rs372305359; called by muse, mutect2, varscan2
- OR4A16 | c.57T>G p.P19= | Silent (SNP) | VAF 76/161 reads (47%) | catalogued as COSV59041827, COSV59044800; called by muse, mutect2, varscan2
- SELP | c.1677C>T p.R559= | Silent (SNP) | VAF 268/433 reads (62%) | catalogued as COSV55257362; called by muse, mutect2, varscan2
- SLC26A9 | c.1098C>T p.N366= | Silent (SNP) | VAF 46/184 reads (25%) | catalogued as COSV61603940; called by muse, mutect2, varscan2
- SUSD4 | c.162T>C p.L54= | Silent (SNP) | VAF 65/182 reads (36%) | catalogued as COSV59555936; called by muse, mutect2, varscan2
- TSHZ3 | c.1839G>A p.L613= | Silent (SNP) | VAF 54/772 reads (7%) | catalogued as rs974270754, COSV53675503; called by muse, mutect2
- TSHZ3 | c.1221C>A p.V407= | Silent (SNP) | VAF 146/1604 reads (9%) | catalogued as COSV99551515; called by muse, mutect2
- VPS13B | c.9996C>T p.D3332= | Silent (SNP) | VAF 36/275 reads (13%) | catalogued as rs754001219, COSV62154321; ClinVar: likely benign; called by muse, mutect2, varscan2
- C16orf82 | c.-91A>C | 5'UTR (SNP) | VAF 68/237 reads (29%) | called by muse, mutect2, varscan2
- DST | c.4297-1461C>T | Intron (SNP) | VAF 100/302 reads (33%) | catalogued as COSV55035374; called by muse, mutect2, varscan2
- KIF13A | chr6:17760870 G>A | 3'Flank (SNP) | VAF 14/26 reads (54%) | catalogued as rs1215413053, COSV52463202; called by muse, mutect2, varscan2
- RIMS2 | c.698+53064C>A | Intron (SNP) | VAF 83/488 reads (17%) | catalogued as COSV51716469; called by muse, mutect2, varscan2
